Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4828, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4828-01A (Primary Tumor).

FINAL DIAGNOSIS

TCGA-B0-4828

- PART 1: KIDNEY, LEFT, RADICAL NEPHRECTOMY-
- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE.
- B. FUHRMAN'S NUCLEAR GRADE III/ IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 9.0 CM.
- D. RENAL CELL CARCINOMA GROWS IN ACINAR PATTERN OF GROWTH.
- E. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- F. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- G. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- I. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- J. THE ADRENAL GLAND IS INVOLVED BY METASTATIC RENAL CELL CARCINOMA (See comment).
- K. TNM STAGE: pT2 Nx M1.
- L. TNM HISTOLOGIC GRADE = G3.
- PART 2: SOFT TISSUE "ANEURYSM CONTENTS", REMOVAL OF AAA CONTENTS-
- A. MULTIPLE FRAGMENTS OF BLOOD CLOT.
- B. NO CARCINOMA SEEN.

COMMENT:

The adrenal gland shows a cystic lesion, composed of clear cells. The fibrovascular pattern, and the morphology of the tumor cells, strongly suggest an origin in the kidney.

A panel of immunohistochemical stains was performed on a section from the tumor in the kidney as well as the tumor in the adrenal gland. The primary renal cell carcinoma is positive for pan cytokeratin and RCC tumor marker. The primary tumor shows aberrant expression of inhibin. The tumor is focally positive for vimentin. The tumor is negative for cytokeratin 7, cytokeratin 20, throglobulin and thyroid transcription factor (TTF). This immunohistochemical profile is consistent with a renal primary.

The tumor in the adrenal is positive for pan cytokeratin and RCC tumor marker. This tumor also shows aberrant

Source: NCI Genomic Data Commons file 83995340-8f78-49e4-b2d9-1a19979cebe1 (TCGA-B0-4828.3AFAEE79-6667-424D-B9DF-CB1F3598EC61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).